Surgical pathology report (de-identified scan), TCGA case TCGA-BR-4292, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-4292-01A (Primary Tumor).

STOMACH TISSUE CHECKLIST Specimen type: Gastrectomy Tumor site: Stomach Tumor size: 5 x 6 x 2.5 cm Tumor features: Exophytic (polypoid) Histologic type: Adenocarcinoma Histologic grade: Well differentiated Tumor extent: Submucosa Lymph nodes: Not specified Lymphatic invasion: Not specified Venous invasion: Not specified Perineural invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

Source: NCI Genomic Data Commons file 71837260-5321-47cf-a274-e71e8a5a4c44 (TCGA-BR-4292.5B5207C1-D37E-4947-BA4F-8FD6090604CF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).